Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JJ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JJ-01A (Primary Tumor).

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Partial organ resection – right breast inner upper quad.

Unit in charge:

Physician in charge:

Material collected on:

Material received on

Expected time of examination: 5 working days

Clinical diagnosis: Inner upper quadrant of the right breast.

1CA-0-3
Carcinoma, infiltrating ductal, nos 854,
Site: breast, nos C50.9

Examination performed on:

Macroscopic description:

Fragment of the right breast sized 6.5 x 5 x 5.2 cm with a 3.5 x 1 cm skin flap, marked typically, no RTG.

Tumour sized 2.1 x 1.5 x 2 cm in the cross section.

Margins: 0.7 cm to the base; 2 cm to the skin surface; 0.2 cm to the sternum; 1.8 cm to the axilla; 2.7 cm to the shoulder; 1 cm to the quadrant boundary.

Postoperative result:

Carcinoma ductale invasivum NHG3 (3 + 3 + 3/35 mitoses/10 HPF - visual area 0.55 mm), pT2.

DCIS foci visible at the tumour edges (solid type with high nuclear atopia, comedo necrosis, 5% of tumour). (DCIS = comedo type necrosis)

Histopathological diagnosis:

Carcinoma ductale invasivum (NHG3, pT2, pN0, SN). Invasive ductal carcinoma of the right breast.

Compliance validated by:

Examination performed on.

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in 10-75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+).

Compliance validated by:

Source: NCI Genomic Data Commons file ae168ce4-f45a-40dd-8c66-267d9e56bf39 (TCGA-D8-A1JJ.3F1DA529-4967-462D-8966-E634D66EB3E1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).